Somatic mutation profile of tumor specimen TCGA-95-7944-01A (aliquot TCGA-95-7944-01A-11D-2184-08) from TCGA case TCGA-95-7944, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.2 years (26,003 days).
Specimen TCGA-95-7944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c21bdf6-493b-4de2-8e62-51d86ada9eb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7944-10A (Blood Derived Normal), aliquot TCGA-95-7944-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d26d1add-37bd-4a6b-83ab-97e23bc9b7a1

The open-access MAF lists 268 somatic variants for this specimen: 185 protein-altering or splice-affecting, 72 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 72, Nonsense Mutation 12, Frame Shift Del 4, Intron 3, Splice Site 3, 5'Flank 2, 3'Flank 2, 3'UTR 2, In Frame Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as COSV54036995; called by muse, mutect2, varscan2
- AC093525.2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | PolyPhen benign (0.003); catalogued as COSV53549638, COSV53550148; called by muse, mutect2, varscan2
- ACSL6 | c.527C>T p.P176L (on ENST00000379240; = p.P201L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760733282, COSV57304734; called by muse, mutect2, varscan2
- ACTB | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV59321121; called by muse, mutect2, varscan2
- ADAM28 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56105186; called by muse, mutect2, varscan2
- ADD2 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV52458830, COSV52470642; called by muse, mutect2, varscan2
- ADGRD1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV55456666; called by muse, mutect2, varscan2
- AGAP6 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100929108; called by muse, mutect2
- AGL | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as COSV54057339; called by muse, mutect2, varscan2
- AKAP1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV58472896; called by muse, mutect2, varscan2
- AMBRA1 | c.1783G>A p.E595K (on ENST00000458649 / NM_001367468.1; = p.E505K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs1208213614, COSV54047898, COSV54062127; called by muse, mutect2
- ANKRD17 | c.3022_3024del p.Q1008del | In Frame Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs759324237; called by pindel, varscan2
- ANKRD30A | c.660A>G p.I220M (on ENST00000611781; = p.I164M on NM_052997.2) | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64620467; called by muse, mutect2, varscan2
- AP3B1 | c.2526G>C p.L842F | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54892448; called by muse, mutect2
- ARMCX6 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV62680937; called by muse, mutect2, varscan2
- ATP6V0A2 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV57752095; called by muse, mutect2, varscan2
- BMP2K | c.2183C>G p.S728* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV55011859; called by muse, mutect2, varscan2
- CACNA1A | c.3208G>C p.D1070H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100801692, COSV64211874; called by muse, mutect2, varscan2
- CALCR | c.1472G>C p.*491Sext*2 (on ENST00000649521 / NM_001164737.2; = p.*475Sext*2 on NM_001742.4) | Nonstop Mutation (SNP) | VAF 33/193 reads (17%) | catalogued as COSV64011623; called by muse, mutect2, varscan2
- CAMLG | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV51805674; called by muse, mutect2, varscan2
- CD300LG | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs772312024, COSV53223476; called by muse, mutect2, varscan2
- CDH23 | c.7989C>G p.F2663L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV56488413; called by muse, mutect2, varscan2
- CDH3 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750498455, COSV50571384; called by muse, mutect2, varscan2
- CDH8 | c.2255G>C p.R752P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as rs370316637, COSV54877455; called by muse, mutect2, varscan2
- CEACAM1 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50732318; called by muse, varscan2
- CENPT | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54652104; called by muse, mutect2, varscan2
- CHGB | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV66761691; called by muse, mutect2, varscan2
- CHRM3 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55080229, COSV55103433, COSV55104375; called by muse, mutect2, varscan2
- CNTRL | c.3521C>G p.S1174* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | catalogued as COSV53053348; called by muse, mutect2, varscan2
- COL27A1 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV61930580; called by muse, mutect2, varscan2
- CORO2A | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.065); catalogued as COSV59661819; called by muse, mutect2, varscan2
- CORO2A | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV59663848, COSV59664854; called by muse, mutect2, varscan2
- CORO2B | c.1344G>C p.E448D | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs778014667, COSV55957157; called by muse, mutect2, varscan2
- CPNE8 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV58851655; called by muse, mutect2, varscan2
- CPT1A | c.1872G>C p.Q624H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55760634; called by muse, mutect2, varscan2
- CRB1 | c.2144G>C p.R715T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV66333401; called by muse, mutect2, varscan2
- CRIP3 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51486014, COSV99240086; called by muse, mutect2, varscan2
- CSTL1 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55679099; called by muse, mutect2, varscan2
- CYP2A6 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.276); catalogued as COSV56537100; called by muse, mutect2, varscan2
- DARS1 | c.818G>T p.R273I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51541861; called by muse, mutect2, varscan2
- DDX18 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV54308443; called by muse, mutect2, varscan2
- DIDO1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV56625507; called by muse, mutect2, varscan2
- DIP2C | c.4115G>C p.G1372A | Missense Mutation (SNP) | VAF 82/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55178251; called by muse, mutect2, varscan2
- DPP10 | c.2040G>C p.L680F | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59724601; called by muse, mutect2, varscan2
- DRD5 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV58580312; called by muse, mutect2, varscan2
- DUSP10 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV60457468; called by muse, varscan2
- DYRK4 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV50544543; called by muse, mutect2, varscan2
- EHMT2 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV64994172; called by muse, mutect2, varscan2
- EPHA4 | c.137T>G p.I46R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as rs1308566551, COSV56043719; called by muse, mutect2, varscan2
- ERAP2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV65940741; called by muse, mutect2
- ESRP1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64409346, COSV64412577; called by muse, mutect2, varscan2
- ETV3 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV58748542; called by muse, varscan2
- FAM181A | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs368140620, COSV50888168; called by muse, mutect2
- FCHO2 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55105595, COSV55111519; called by muse, mutect2
- FGFR2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV60642023; called by muse, mutect2, varscan2
- FOXF1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285911; called by muse, mutect2, varscan2
- FUT7 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377124986, COSV55806409; called by muse, mutect2, varscan2
- GALK1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52332374; called by muse, mutect2, varscan2
- GAPDHS | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55883889; called by muse, mutect2, varscan2
- GLDC | c.2261A>G p.K754R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58684920; called by muse, mutect2, varscan2
- GLYATL1 | c.706G>T p.E236* (on ENST00000317391 / NM_001354699.1; = p.E267* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV55611334; called by muse, mutect2, varscan2
- GNAI1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV63524203, COSV63525072; called by muse, mutect2, varscan2
- GPR160 | c.792A>T p.L264F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV63473543; called by muse, mutect2, varscan2
- GRID2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56234110; called by muse, mutect2, varscan2
- GRIK5 | c.815C>A p.T272K | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV53483436, COSV53485400; called by muse, mutect2, varscan2
- GUCY1A1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV56656335; called by muse, mutect2, varscan2
- GUCY1A2 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56501253; called by muse, mutect2, varscan2
- HOXC11 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54534046; called by muse, mutect2, varscan2
- HRG | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV51648175; called by muse, mutect2, varscan2
- HS3ST2 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.229); catalogued as COSV54468455; called by muse, mutect2, varscan2
- HS3ST5 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV57151611; called by muse, mutect2, varscan2
- IARS2 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56963826; called by muse, mutect2, varscan2
- IFT172 | c.3314G>C p.R1105T | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs200867341, COSV53137740; called by muse, mutect2, varscan2
- IGSF1 | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63837491, COSV63839716; called by muse, mutect2, varscan2
- IL20RB | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59049769; called by muse, mutect2, varscan2
- ITPR1 | c.7561G>T p.E2521* (on ENST00000354582; = p.E2466* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV57002574; called by muse, mutect2, varscan2
- ITPRID1 | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs763405857, COSV100087776, COSV60082312; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1299G>C p.Q433H (on ENST00000439118 / NM_001008949.3; = p.Q441H on NM_178495.6) | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV63154619; called by muse, mutect2, varscan2
- KDM5D | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV58737260; called by muse, mutect2, varscan2
- KIF19 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV63430550; called by muse, mutect2, varscan2
- LEPR | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60764059; called by muse, mutect2, varscan2
- LINS1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV59080886; called by muse, mutect2, varscan2
- LPCAT1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV52041143; called by muse, mutect2, varscan2
- LPCAT4 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV59218932; called by muse, mutect2, varscan2
- LRGUK | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV53642654; called by muse, mutect2, varscan2
- LRP2 | c.12094T>C p.C4032R | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55573191; called by muse, mutect2, varscan2
- LZTR1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs5761750, COSV53146208; called by muse, mutect2, varscan2
- MAGEF1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs763896480, COSV58634363; called by muse, mutect2, varscan2
- MAGI2 | c.3837G>T p.Q1279H | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100835490; called by muse, mutect2, varscan2
- METTL22 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV50838731; called by muse, mutect2, varscan2
- MROH7 | c.3963G>C p.L1321F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV64888262, COSV64888306; called by muse, mutect2, varscan2
- MYO1F | c.2199C>A p.N733K | Missense Mutation (SNP) | VAF 104/525 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.67); catalogued as COSV57800027; called by muse, mutect2, varscan2
- NBPF1 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 39/720 reads (5%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.58); catalogued as COSV55329401; called by muse, mutect2
- NCK1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56639763; called by muse, mutect2, varscan2
- NEDD4 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV59066479; called by muse, mutect2, varscan2
- NMBR | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57803229; called by muse, mutect2, varscan2
- NPFFR2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV58154124; called by muse, mutect2, varscan2
- OR10A2 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV56300487; called by muse, mutect2, varscan2
- OR4C16 | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV58944247; called by muse, mutect2, varscan2
- OR52K1 | c.736C>G p.H246D | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56904704; called by muse, mutect2, varscan2
- PAIP1 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV59087771; called by muse, mutect2, varscan2
- PANK1 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1277957595, COSV56810472; called by muse, mutect2, varscan2
- PCBP3 | c.225T>A p.S75R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68409977, COSV68410026; called by muse, mutect2, varscan2
- PCDHB12 | c.1218G>C p.E406D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.119); catalogued as COSV53395299, COSV53400836; called by muse, mutect2, varscan2
- PCDHGC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452697214, COSV52744109; called by muse, mutect2
- PDZD2 | c.5875G>C p.E1959Q | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV56872049; called by muse, mutect2, varscan2
- PHKG1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52081680; called by muse, mutect2, varscan2
- PIAS2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61345313; called by muse, mutect2, varscan2
- PLXNA4 | c.3953G>C p.R1318T | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58158867; called by muse, mutect2
- PMFBP1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52820013, COSV52831560; called by muse, mutect2, varscan2
- POLR3C | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV61937510; called by muse, mutect2, varscan2
- POU2F2 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV60766526; called by muse, mutect2, varscan2
- PPP1R9A | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1199747850, COSV56909874; called by muse, mutect2, varscan2
- PRDM14 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52574594; called by muse, mutect2, varscan2
- PRDM16 | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2, varscan2
- PSG7 | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 148/699 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV68444247, COSV68446558; called by muse, mutect2, varscan2
- PTPN2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58999063; called by muse, mutect2
- RASGRF1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV67249620; called by muse, mutect2, varscan2
- RASGRF1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV69178848, COSV69183119; called by muse, varscan2
- RASSF8 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV51455263; called by muse, mutect2, varscan2
- RBM28 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV56164784; called by muse, mutect2, varscan2
- RC3H2 | c.1729C>A p.Q577K | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV61802393; called by muse, mutect2, varscan2
- RECQL4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV52878613, COSV52882679; called by muse, mutect2, varscan2
- REG3G | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 40/242 reads (17%) | catalogued as rs147143164, COSV99709552; called by muse, mutect2, varscan2
- RNF10 | c.2357C>T p.S786F | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV58048107; called by muse, mutect2, varscan2
- RNF138 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55235643, COSV99857530; called by muse, mutect2, varscan2
- RNPEP | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV55244034; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV59088468; called by muse, mutect2, varscan2
- RTN4RL2 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs754116484, COSV58652999; called by muse, mutect2, varscan2
- RUVBL2 | c.1367-1G>A p.X456_splice | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as COSV55487138; called by muse, mutect2
- RYR2 | c.8972G>T p.C2991F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV63712264; called by muse, mutect2, varscan2
- SAMD9L | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59085075; called by muse, mutect2, varscan2
- SAV1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV61204369, COSV61205739; called by muse, mutect2, varscan2
- SCAPER | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV57753620; called by muse, mutect2, varscan2
- SELENOF | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV59357155; called by muse, mutect2, varscan2
- SLC6A16 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV60030316; called by muse, mutect2, varscan2
- SMTNL1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); catalogued as COSV67700680; called by muse, mutect2
- SMYD4 | c.2021-1G>C p.X674_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59713612; called by muse, mutect2
- SOAT2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | catalogued as COSV56857934; called by muse, mutect2, varscan2
- SOX5 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58647459; called by muse, mutect2, varscan2
- SPAG17 | c.4516G>C p.E1506Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60455721; called by muse, mutect2, varscan2
- SPI1 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57048036; called by muse, mutect2, varscan2
- SPIRE2 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs146263316; called by muse, mutect2, varscan2
- SPRR3 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV54880410, COSV54881345; called by muse, mutect2, varscan2
- SSTR5 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53513480; called by muse, mutect2, varscan2
- STAMBP | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100277629, COSV59898361; called by muse, mutect2, varscan2
- SULT1A1 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV59090639; called by muse, mutect2, varscan2
- TARS1 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV54312262; called by muse, mutect2, varscan2
- TBXA2R | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs769254342, COSV100916326, COSV64344649; called by muse, mutect2, varscan2
- TENT2 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57139247; called by muse, mutect2, varscan2
- TESPA1 | c.1398G>C p.Q466H (on ENST00000316577 / NM_001098815.3; = p.Q328H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57261243; called by muse, mutect2, varscan2
- TFIP11 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68021346; called by muse, mutect2, varscan2
- TMEM196 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs200293383, COSV68256431; called by muse, mutect2, varscan2
- TNRC6C | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56940739, COSV56945026; called by muse, mutect2, varscan2
- TRPC4 | c.2100G>C p.L700F (on ENST00000379705 / NM_016179.4; = p.L705F on NM_003306.3) | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV59018084; called by muse, mutect2, varscan2
- TRPC4 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59018110; called by muse, mutect2, varscan2
- TUBB | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58358323; called by muse, mutect2, varscan2
- TUT4 | c.4175G>T p.R1392L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57118597, COSV99932586; called by muse, mutect2, varscan2
- TUT4 | c.4174C>T p.R1392C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs143272455; called by muse, mutect2, varscan2
- UBE2E3 | c.510G>C p.L170F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as COSV66586369; called by muse, mutect2, varscan2
- ULK4 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.649); catalogued as COSV57222809; called by muse, mutect2, varscan2
- UNC5A | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56169489, COSV56172288; called by muse, mutect2, varscan2
- USP14 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV55280322, COSV55283400; called by muse, mutect2, varscan2
- VCAN | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV54116158; called by muse, mutect2, varscan2
- VSIG2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as rs773351789, COSV52519466; called by muse, mutect2, varscan2
- WDR72 | c.2324C>G p.S775C | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV64746940, COSV64753749; called by muse, mutect2, varscan2
- WNT3A | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV52733867; called by muse, mutect2, varscan2
- ZCCHC4 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs779832307, COSV57183370; called by muse, mutect2, varscan2
- ZDBF2 | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV65623135; called by muse, mutect2, varscan2
- ZMYND11 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.171); catalogued as rs1282678709, COSV59081884; called by muse, mutect2, varscan2
- ZNF132 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as rs148462540, COSV54236218; called by muse, mutect2, varscan2
- ZNF132 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV54236273; called by muse, mutect2, varscan2
- ZNF132 | c.1145G>C p.R382T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs200814507; called by muse, mutect2, varscan2
- ZNF132 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV54236297, COSV99571032; called by muse, mutect2, varscan2
- ZNF233 | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV61934685; called by muse, mutect2, varscan2
- ZNF335 | c.1103-1G>A p.X368_splice | Splice Site (SNP) | VAF 16/103 reads (16%) | catalogued as COSV59820104; called by muse, mutect2, varscan2
- ZNF462 | c.7072G>C p.E2358Q | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52950449; called by muse, mutect2, varscan2
- ZNF813 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV67176225; called by muse, mutect2, varscan2
- CKS2 | c.151_152del p.L52Rfs*9 | Frame Shift Del (DEL) | VAF 34/208 reads (16%) | called by pindel, varscan2
- IGBP1P2 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MAD1L1 | c.1231_1249del p.M411Pfs*6 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by pindel, varscan2*
- NF1 | c.6590_6591del p.F2197Cfs*44 (on ENST00000358273 / NM_001042492.3; = p.F2176Cfs*44 on NM_000267.3) | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | called by mutect2, pindel, varscan2
- SYNRG | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XRN2 | c.2521del p.Y841Tfs*10 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | called by mutect2, pindel, varscan2
- ACTC1 | c.234C>T p.I78= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs1393400015, COSV51761360; called by muse, mutect2, varscan2
- ANO8 | c.3627C>G p.L1209= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs768976940, COSV50198484; called by muse, mutect2, varscan2
- AOPEP | c.499C>T p.L167= | Silent (SNP) | VAF 47/257 reads (18%) | catalogued as COSV52923612; called by muse, mutect2, varscan2
- ATP10D | c.2460G>A p.Q820= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV56712948; called by muse, mutect2, varscan2
- BANF2 | c.93C>T p.L31= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs776837870, COSV55724779; called by muse, mutect2, varscan2
- CAMSAP3 | c.1569C>A p.P523= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV50336397; called by muse, mutect2, varscan2
- CARS2 | c.489G>C p.L163= | Silent (SNP) | VAF 38/225 reads (17%) | catalogued as COSV57289046, COSV99959696, COSV99960110; called by muse, mutect2, varscan2
- CDCA8 | c.537G>A p.V179= | Silent (SNP) | VAF 75/395 reads (19%) | catalogued as COSV59240405; called by muse, mutect2, varscan2
- CHRNB4 | c.717C>T p.L239= | Silent (SNP) | VAF 38/251 reads (15%) | catalogued as COSV55718239; called by muse, mutect2, varscan2
- CHSY3 | c.1407G>C p.L469= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV59287763; called by muse, mutect2
- CLIP4 | c.1116C>T p.I372= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1347831044, COSV60752616; called by muse, mutect2, varscan2
- DNMT3B | c.1386C>T p.F462= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV52423077; called by muse, mutect2, varscan2
- DSG3 | c.156G>A p.V52= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV57129547; called by muse, mutect2, varscan2
- EPHX2 | c.1455G>C p.L485= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV66846021; called by muse, mutect2, varscan2
- ERBB3 | c.2928G>A p.L976= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV57262911; called by muse, mutect2, varscan2
- EYA1 | c.1704G>A p.A568= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs761954788, COSV58173641; called by muse, mutect2, varscan2
- EYA4 | c.141T>C p.T47= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs752686762, COSV62060413; called by muse, mutect2, varscan2
- FLG2 | c.954G>A p.Q318= | Silent (SNP) | VAF 63/384 reads (16%) | catalogued as COSV66173004; called by muse, mutect2, varscan2
- FLNC | c.5409G>A p.R1803= | Silent (SNP) | VAF 40/203 reads (20%) | catalogued as COSV57964362; called by muse, mutect2, varscan2
- FUS | c.993C>G p.G331= | Silent (SNP) | VAF 21/203 reads (10%) | catalogued as COSV54219657; called by muse, mutect2, varscan2
- GYS1 | c.1740G>C p.R580= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV54405262; called by muse, mutect2, varscan2
- HERC2 | c.1686C>T p.Y562= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs1285371352, COSV55349276; called by muse, mutect2, varscan2
- HYDIN | c.11157C>T p.I3719= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV66642250; called by muse, mutect2, varscan2
- ITGAD | c.2400G>A p.V800= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as COSV66760102; called by muse, mutect2, varscan2
- KRCC1 | c.301C>T p.L101= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs997107610, COSV61252242; called by muse, mutect2, varscan2
- LRP2 | c.2916C>T p.N972= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs142290901; called by muse, mutect2, varscan2
- LRRC4 | c.732C>T p.L244= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs771130627, COSV50818034, COSV99974840; called by muse, mutect2, varscan2
- MEGF8 | c.5550G>A p.G1850= (on ENST00000251268 / NM_001271938.2; = p.G1783= on NM_001410.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV52100799; called by muse, mutect2, varscan2
- MESP2 | c.357G>T p.L119= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59093593; called by muse, mutect2, varscan2
- METTL23 | c.435C>G p.L145= | Silent (SNP) | VAF 168/449 reads (37%) | catalogued as rs777437823, COSV57973572, COSV57975672; called by muse, mutect2, varscan2
- METTL8 | c.447G>A p.V149= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV64551690; called by muse, mutect2, varscan2
- MNT | c.771T>C p.N257= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV51513959; called by muse, mutect2, varscan2
- MUC17 | c.846C>A p.L282= | Silent (SNP) | VAF 144/403 reads (36%) | catalogued as COSV60285818; called by muse, mutect2, varscan2
- MX1 | c.327G>A p.L109= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV55820835; called by muse, mutect2, varscan2
- MYO5A | c.4803G>A p.V1601= | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as COSV62564565; called by muse, varscan2
- NEK6 | c.66G>A p.G22= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57221144; called by muse, mutect2
- NFAT5 | c.1713C>T p.A571= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV63032449; called by muse, mutect2, varscan2
- OPN1SW | c.672G>C p.L224= | Silent (SNP) | VAF 37/240 reads (15%) | catalogued as rs1554370107, COSV50823361; called by muse, mutect2, varscan2
- OR10A2 | c.894C>T p.L298= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV56300496; called by muse, mutect2
- OR5H6 | c.909C>T p.P303= (on ENST00000642105; = p.P287= on NM_001005479.2) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV101051741, COSV67352070; called by muse, mutect2, varscan2
- ORC4 | c.153G>T p.L51= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV51577100, COSV99932009; called by muse, mutect2, varscan2
- PBRM1 | c.9C>A p.S3= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV56303051; called by muse, mutect2, varscan2
- PCSK6 | c.2862G>A p.R954= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61860334; called by muse, mutect2, varscan2
- PDE4A | c.1614C>T p.I538= (on ENST00000380702 / NM_001111307.2; = p.I299= on NM_006202.3) | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV53362013, COSV99535061; called by muse, mutect2, varscan2
- PHLDB2 | c.579C>T p.I193= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV67315766; called by muse, mutect2, varscan2
- POU5F2 | c.582G>A p.E194= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV67941817; called by muse, mutect2, varscan2
- PRSS54 | c.711G>A p.L237= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1463515411, COSV54687776; called by muse, mutect2, varscan2
- PTPRF | c.1683C>T p.F561= | Silent (SNP) | VAF 62/268 reads (23%) | catalogued as rs778116534, COSV63448675; called by muse, mutect2, varscan2
- PZP | c.1998C>G p.L666= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV54369860; called by muse, mutect2, varscan2
- RBM17 | c.1110T>G p.V370= | Silent (SNP) | VAF 14/320 reads (4%) | catalogued as COSV65914897; called by muse, mutect2
- RBM4B | c.63C>G p.L21= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs754073843, COSV59498128; called by muse, mutect2, varscan2
- RESF1 | c.4575G>A p.Q1525= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100440297, COSV57025472; called by muse, mutect2, varscan2
- RHBDF1 | c.1101G>A p.E367= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1213167991, COSV51957880; called by muse, mutect2, varscan2
- ROBO2 | c.150G>T p.L50= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV59907197; called by muse, mutect2, varscan2
- SELENOO | c.1161G>A p.R387= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV66600408; called by muse, mutect2, varscan2
- SETX | c.6465G>A p.L2155= | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as COSV56394228; called by muse, mutect2, varscan2
- SLC35F2 | c.1119C>T p.V373= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV56183763; called by muse, mutect2, varscan2
- SLC36A1 | c.471C>G p.V157= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as COSV54656242; called by muse, mutect2, varscan2
- SLC39A5 | c.885C>T p.L295= | Silent (SNP) | VAF 75/431 reads (17%) | catalogued as COSV57193584; called by muse, mutect2, varscan2
- SPG11 | c.1356C>T p.L452= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV55998689, COSV56001715; called by muse, mutect2, varscan2
- SULT1C4 | c.114C>T p.I38= | Silent (SNP) | VAF 73/313 reads (23%) | catalogued as COSV55598901; called by muse, mutect2, varscan2
- SYT10 | c.537G>A p.P179= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs778172972, COSV57340490, COSV57345326; called by muse, mutect2, varscan2
- SYTL3 | c.1524C>T p.L508= (on ENST00000611299 / NM_001242394.1; = p.L440= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV51907520; called by muse, mutect2, varscan2
- TANC1 | c.24G>A p.K8= | Silent (SNP) | VAF 43/224 reads (19%) | catalogued as COSV55096468; called by muse, mutect2, varscan2
- TLE4 | c.1374G>A p.Q458= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV54640954; called by muse, mutect2, varscan2
- TLN2 | c.1965G>C p.L655= | Silent (SNP) | VAF 40/207 reads (19%) | catalogued as COSV60890885, COSV60895477; called by muse, mutect2, varscan2
- TMTC3 | c.1398G>A p.L466= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV57124745, COSV57126253; called by muse, mutect2, varscan2
- TNFAIP2 | c.921C>T p.L307= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100281099, COSV60696104; called by muse, mutect2, varscan2
- TRIM71 | c.2520G>A p.Q840= | Silent (SNP) | VAF 83/335 reads (25%) | catalogued as rs763824262, COSV67472618; called by muse, mutect2, varscan2
- U2AF1L4 | c.543C>A p.L181= (on ENST00000412391; = p.S123Y on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53076537; called by muse, mutect2
- XIRP1 | c.1386G>C p.G462= | Silent (SNP) | VAF 89/309 reads (29%) | catalogued as COSV61140915; called by muse, mutect2, varscan2
- ZNF30 | c.57G>T p.V19= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57852901, COSV57855319; called by muse, mutect2, varscan2
- AP3D1 | c.-1G>C | 5'UTR (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100642615, COSV100642898; called by muse, mutect2, varscan2
- COLCA2 | chr11:111296102 C>T | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- DCHS2 | n.2030A>T | RNA (SNP) | VAF 53/175 reads (30%) | catalogued as COSV59738920; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726769 C>T | 3'Flank (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- FAS | c.*107G>A | 3'UTR (SNP) | VAF 30/120 reads (25%) | catalogued as COSV58240073; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901081 G>A | 3'Flank (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+4052G>A | Intron (SNP) | VAF 52/192 reads (27%) | catalogued as COSV100169309; called by muse, mutect2, varscan2
- OBSCN | c.11659+3458G>A | Intron (SNP) | VAF 45/231 reads (19%) | catalogued as COSV99481962; called by muse, mutect2, varscan2
- PXN | c.831+1892C>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- RTL8A | c.*1G>C | 3'UTR (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100887741; called by muse, varscan2
- UCHL5 | chr1:193059779 G>T | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100814665; called by muse, mutect2, varscan2
